Surgical pathology report (de-identified scan), TCGA case TCGA-FL-A1YM, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Hawaii - Normal Study, specimen TCGA-FL-A1YM-11A (Solid Tissue Normal).

[page 1 of 2]
Surgical Pathology Report

Patient Name: [REDACTED]

Med. Rec. #: [REDACTED]

DOB: [REDACTED]

Gender: F

Physician(s): [REDACTED]

cc: [REDACTED]

Client: [REDACTED]

Location: [REDACTED]

Accession #: [REDACTED]

Taken: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

History/Clinical Dx: Atypical endometrial hyperplasia

Postoperative Dx: Pending pathology examination

Specimen(s) Received:

Uterus, cervix, tubes and ovaries

DIAGNOSIS:

Uterus, cervix, tubes and ovaries:

1. Cervix with no pathologic abnormality
2. Complex hyperplasia with atypia, focal
3. Endometrial polyp containing complex hyperplasia with atypia
4. Adenomyosis (4)
5. Bilateral ovaries with benign serous cysts
6. Right fallopian tube with no pathologic abnormality
7. Left fallopian tube with paratubal cyst

Gross Description

Received in formalin labeled "uterus, tubes, ovaries" consist of a uterus and cervix with attached adnexal structures weighing altogether 139 gm. The specimen has been previously bi-valved. The uterine corpus measures 7.0 x 6.0 x 3.0 cm. The serosal surface is tan pink and smooth. The cervix measures 3.0 cm in length and 3.5 cm in diameter. The exocervical mucosa is tan and smooth. A white-tan, friable, polypoid mass is present of the endometrial surface measuring 1.5 cm in greatest dimension. It appears to be superficial. The remainder of the endometrial surface is tan pink and smooth. The myometrium is serially sectioned to reveal a well circumscribed white tan nodule measuring 0.5 cm in greatest dimension. The right ovary is tan and cerebiform measuring 2.5 cm in greatest dimension. Cut surface reveals smooth walled cyst measuring up to 0.8 cm in greatest dimension. The right fallopian tube measures 7.0 cm in length and 0.5 cm in diameter. The left ovary measures 1.5 cm in greatest dimension. Cut sections are unremarkable. The left fallopian tube measures 6.0 cm in length and 0.5 cm in diameter. A paratubal cyst is present. The bilateral fallopian tubes show evidence of previous ligation. The myometrium measures 2.5 cm in greatest thickness. Representative sections are submitted as follows:

KEY TO CASSETTES:

- | | | |
|-----|---|--------------------------|
| 1 | - | Cervix |
| 2 | - | Polypoid mass |
| 3-6 | - | Endometrium |
| 7 | - | Myometrial mass |
| 8 | - | Right adnexal structures |

100-0-3 not applicable

Normal path from non-cancer patient.

ju 11/11

Reagent Information

The following statement may be applicable to some of the reagents/antibodies used in developing the above report: This test was developed and its performance characteristics determined by [redacted] not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as a substitute for the results. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

[page 2 of 2]
[REDACTED]

[REDACTED]

Surgical Pathology Report

9 - Left adnexal structures

Microscopic Description

The microscopic findings support the above diagnoses.

[REDACTED]

Source: NCI Genomic Data Commons file 0fbcfefa-8581-48da-b1e0-3c44946dc255 (TCGA-FL-A1YM.5FCF83F3-5851-476C-87F6-2DEDF2669A6C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).